Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72L, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72L-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3
Carcinoma renal cell
chromophobe type 8317/3
① Kidney NOS
C64.9
QW8/9/13

Diagnosis:

A: Renal mass #1, biopsy

- Renal cell carcinoma, chromophobe type, nuclear grade 2 (of 4)

B: Kidney, base of tumor #1, biopsy

- Benign renal parenchyma, no tumor seen

C: Kidney mass #2, partial nephrectomy

Histologic tumor type/subtype: Renal cell carcinoma, chromophobe type

Sarcomatoid features: Not identified

Histologic grade (if applicable): 2 (of 4)

Tumor size (greatest dimension): 9 mm

Tumor focality: Multifocal, there are 3 separate tumors in this patient.

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: Not identified

Gerota' s fascia: Not identified

Renal sinus: Not present in specimen

Major veins (renal vein or segmental branches, IVC): Not present in specimen

Ureter: Not present in specimen

Venous (large vessel): Not identified

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): Free of tumor

Renal capsular margin (partial nephrectomy only): Free of tumor

Paranephric adipose tissue margin (partial nephrectomy only):

Free of tumor

Adrenal gland: Not present in specimen

Lymph nodes: None present in specimen

[page 2 of 3]
Other significant findings: None

AJCC Staging:

pT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

D: Renal mass #3, partial nephrectomy

Histologic tumor type/subtype: Renal cell carcinoma, chromophobe type

Sarcomatoid features: Not identified

Histologic grade (if applicable): 3 (of 4)

Tumor size (greatest dimension): 2.7 cm

Tumor focality: Multifocal, there are 3 separate tumors in this patient.

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: Not identified

Gerota' s fascia: Not identified

Renal sinus: Not present in specimen

Major veins (renal vein or segmental branches, IVC): Not present in specimen

Ureter: Not present in specimen

Venous (large vessel): Not identified

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): Free of tumor

Renal capsular margin (partial nephrectomy only): Free of tumor

Paranephric adipose tissue margin (partial nephrectomy only): Free of tumor

Adrenal gland: Not present in specimen

Lymph nodes: None present in specimen

[page 3 of 3]
Other significant findings: None

AJCC Staging:

pT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old female with renal masses.

Gross Description:

Received are four formalin-filled containers.

Container A is additionally labeled "renal mass #1." It consists of a 0.7 x 0.5 x 0.4 cm fragment of pink/tan rubbery tissue that is inked blue, bisected and submitted in block A1,

Container B is additionally labeled "base of tumor #1." It consists of a 0.4 x 0.1 x 0.1 cm fragment of soft pink/tan tissue submitted in block B1,

Container C is additionally labeled "renal mass #2." It consists of a 1 gram (1.6 x 1.2 x 0.9 cm) partial nephrectomy that has a 0.9 x 0.9 x 0.8 cm well circumscribed smooth tan rubbery nodule. The nodule abuts the capsule (inked yellow) and is 0.3 cm from the parenchymal margin (inked black). The specimen is sectioned perpendicular to the parenchymal margin and submitted in blocks C1 and C2.

Container D is additionally labeled "renal mass #3." It consists of a 17 gram (3.4 x 3.1 x 3.0 cm) partial nephrectomy. Approximately 75% of the cut surface is involved by a 2.7 x 2.7 x 2.5 cm well circumscribed smooth tan rubbery nodule that bulges the capsule (inked yellow) and is 0.5 cm from the parenchymal margin (inked black). A portion of the nodule is given to _____ and perpendicular sections of nodule with capsule is submitted in block D1, and perpendicular sections of nodule with parenchymal margin is submitted in blocks D2-D4.

Source: NCI Genomic Data Commons file bd5cc7ae-21c5-4ab6-9305-1876b239377c (TCGA-UW-A72L.F0BF5DE6-7AA1-43CF-9A1B-AE40BFC79379.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).